Somatic mutation profile of tumor specimen 0DAU0F from CCDI case PBBKIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,541 days).
Specimen 0DAU0F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6e3f2c6-0404-4893-b1d9-68fc9b5cf35b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DATZZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db2b4607-92f2-439b-b089-dc397150e2d1

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP6 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 19/538 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057071194; called by muse, mutect2
- ASXL3 | c.6101C>T p.P2034L | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
